Somatic mutation profile of tumor specimen TCGA-B8-A54E-01A (aliquot TCGA-B8-A54E-01A-11D-A25V-10) from TCGA case TCGA-B8-A54E, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.7 years (22,900 days).
Specimen TCGA-B8-A54E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0b99260-b8c9-4818-9d33-2db3fb236c7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-A54E-10A (Blood Derived Normal), aliquot TCGA-B8-A54E-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b25406d-aa40-4fee-a602-48b3fc748532

The open-access MAF lists 45 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, Frame Shift Del 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAAS | c.338G>T p.W113L | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as COSV99267152; called by muse, mutect2, varscan2
- ADGRB1 | c.4567C>A p.Q1523K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.628); catalogued as COSV100030496; called by muse, mutect2, varscan2
- CCDC89 | c.380T>C p.M127T | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV100320929; called by muse, mutect2, varscan2
- CCDC96 | c.1641G>T p.R547S | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV100028134; called by muse, mutect2, varscan2
- CHD9 | c.4972A>G p.I1658V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.847); catalogued as rs950170067, COSV99529852; called by muse, varscan2
- DDX5 | c.1063G>C p.D355H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99858357; called by muse, mutect2, varscan2
- FAM171A1 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs547476247, COSV65315842; called by muse, mutect2, varscan2
- FOLH1 | c.1634A>G p.K545R | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99924043; called by muse, mutect2
- FREM2 | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99751364; called by muse, mutect2, varscan2
- GRHL3 | c.293C>T p.T98M (on ENST00000350501 / NM_198174.3; = p.T103M on NM_021180.3) | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs372226155; called by muse, mutect2, varscan2
- GUCY1A2 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99977321; called by muse, mutect2, varscan2
- HEATR5A | c.3899T>C p.I1300T | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs746649383, COSV101120649; called by muse, mutect2, varscan2
- HSP90AA1 | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99355557; called by muse, mutect2, varscan2
- LCN1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV99704545; called by muse, mutect2, varscan2
- MED12 | c.2819A>T p.N940I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61361406; called by muse, mutect2, varscan2
- MEGF10 | c.3199T>A p.S1067T | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV99175817; called by muse, mutect2, varscan2
- MUC16 | c.4417G>T p.D1473Y | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); catalogued as rs1314502910, COSV101201980, COSV67492294; called by muse, mutect2
- NLE1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.096); catalogued as COSV99339105; called by muse, mutect2, varscan2
- NPHS1 | c.1112T>A p.L371Q | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.212); catalogued as COSV100800313; called by muse, mutect2
- PCNX1 | c.3902G>T p.G1301V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs202214990; called by muse, mutect2, varscan2
- PHB | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV100303271; called by muse, mutect2, varscan2
- PLXNA4 | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0.044); catalogued as COSV100327676; called by muse, mutect2, varscan2
- PRSS12 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs758938961, COSV99628956; called by muse, mutect2, varscan2
- PTK2 | c.805T>G p.S269A | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.099); catalogued as COSV100571318; called by muse, mutect2, varscan2
- SCN5A | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100350978; called by muse, mutect2, varscan2
- SLC26A11 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs143498900, COSV63278807; called by muse, mutect2, varscan2
- SLC28A3 | c.415A>G p.I139V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.109); catalogued as COSV100883360; called by muse, mutect2, varscan2
- SNX1 | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as COSV99976448; called by muse, mutect2, varscan2
- TMC2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV100728039; called by mutect2, varscan2
- TRAF4 | c.1410C>A p.S470R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV99286605; called by muse, mutect2, varscan2
- VEGFD | c.956C>A p.P319H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99938578; called by muse, mutect2, varscan2
- ZBTB14 | c.1214A>G p.K405R | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.956); catalogued as COSV100813518; called by muse, mutect2, varscan2
- ZSWIM4 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV99585497; called by muse, mutect2, varscan2
- DHRS7C | c.921del p.N307Kfs*? (on ENST00000330255 / NM_001220493.2; = p.N306Kfs*? on NM_001105571.3) | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- GLB1 | c.321del p.L108Ffs*13 | Frame Shift Del (DEL) | VAF 27/156 reads (17%) | called by mutect2, pindel, varscan2
- TLN2 | c.7059del p.I2353Mfs*42 | Frame Shift Del (DEL) | VAF 17/135 reads (13%) | called by mutect2, pindel, varscan2
- AC245033.1 | c.1731C>T p.F577= | Silent (SNP) | VAF 41/203 reads (20%) | called by muse, mutect2, varscan2
- KCNA3 | c.1266C>T p.D422= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV63901657; called by muse, mutect2, varscan2
- NASP | c.1728G>A p.L576= | Silent (SNP) | VAF 40/200 reads (20%) | catalogued as COSV100602041; called by muse, mutect2, varscan2
- PTPRN2 | c.2526C>T p.I842= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs759623053, COSV66104780; called by muse, mutect2, varscan2
- PTPRO | c.3444C>T p.A1148= (on ENST00000281171 / NM_030667.3; = p.A1120= on NM_002848.4) | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV55503646; called by muse, mutect2, varscan2
- SPG11 | c.6072G>A p.L2024= | Silent (SNP) | VAF 23/155 reads (15%) | catalogued as COSV99969776; called by muse, mutect2, varscan2
- TRAF1 | c.390G>A p.L130= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100875225, COSV65869444; called by muse, mutect2, varscan2
- ZNF778 | c.1797C>G p.T599= | Silent (SNP) | VAF 25/154 reads (16%) | catalogued as COSV100124744; called by muse, mutect2, varscan2
- INSIG1 | c.804+1040G>A | Intron (SNP) | VAF 9/59 reads (15%) | catalogued as rs765920985, COSV100453129; called by muse, mutect2, varscan2
